Somatic mutation profile of tumor specimen MMRF_1838_2_BM_CD138pos (aliquot MMRF_1838_2_BM_CD138pos_T1_KBS5U_L07293) from MMRF case MMRF_1838, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.7 years (26,537 days).
Specimen MMRF_1838_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cde3daca-28cc-46f5-aa77-853d21831a77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1838_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1838_1_PB_Whole_C2_KBS5U_L07286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3035987-6425-413a-be0d-9605402c5ca8

The open-access MAF lists 51 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, 3'UTR 16, Silent 8, Intron 3, 3'Flank 2, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 64/156 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANO4 | c.1192C>T p.P398S (on ENST00000392977 / NM_001286615.2; = p.P363S on NM_178826.4) | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54585932; called by muse, mutect2, varscan2
- FZD1 | c.322A>T p.I108F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.359); catalogued as COSV99842632; called by muse, mutect2
- IGHV2-70 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.701); catalogued as rs376644103; called by muse, varscan2
- KCTD16 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs868542964, COSV72579641; called by muse, mutect2, varscan2
- KLF7 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs536720710, COSV100519156; called by muse, mutect2, varscan2
- NEUROD4 | c.795G>T p.L265F | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV54473321; called by muse, mutect2, varscan2
- NLGN2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs753026024; called by muse, mutect2, varscan2
- NSFL1C | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as rs1193514014; called by muse, mutect2, varscan2
- OLFM3 | c.957G>T p.M319I (on ENST00000338858 / NM_001288821.1; = p.M299I on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1054467118; called by muse, mutect2
- OR2T34 | c.531G>T p.R177S | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100170301, COSV60899697; called by muse, mutect2
- ZEB2 | c.1835C>A p.A612E | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.999); catalogued as COSV57958275; called by muse, mutect2, varscan2
- ZNF805 | c.953_954del p.K318Rfs*9 | Frame Shift Del (DEL) | VAF 65/180 reads (36%) | catalogued as rs1290681275; called by mutect2, pindel, varscan2
- ARFGEF2 | c.2825A>T p.D942V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C22orf23 | c.524T>C p.M175T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRAMD1A | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2
- GRSF1 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- IQCE | c.1978C>G p.P660A | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF5C | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- OSBPL6 | c.1445A>T p.N482I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SEPTIN6 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2
- CRACDL | c.1872C>T p.H624= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- CYP4F3 | c.915C>T p.S305= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as rs1426856546; called by muse, mutect2, varscan2
- HECW1 | c.1734G>A p.A578= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as COSV67840222; called by muse, mutect2, varscan2
- MYH14 | c.2655G>A p.Q885= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as rs1261380486; called by mutect2, varscan2
- MYL1 | c.582C>T p.I194= | Silent (SNP) | VAF 131/324 reads (40%) | called by muse, mutect2, varscan2
- MYO16 | c.282G>T p.G94= | Silent (SNP) | VAF 57/146 reads (39%) | catalogued as rs769013062; called by muse, mutect2, varscan2
- SLC2A13 | c.1533G>A p.L511= | Silent (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- WRN | c.1236A>G p.E412= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as rs746496708; called by muse, mutect2, varscan2
- ATAD2B | c.*420del | 3'UTR (DEL) | VAF 28/80 reads (35%) | catalogued as rs924998091; called by mutect2, varscan2
- C6orf118 | c.*373A>C | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
- CDC42SE1 | chr1:151050976 G>A | 3'Flank (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- COL21A1 | c.*701C>T | 3'UTR (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- CTDSP1 | c.*910C>T | 3'UTR (SNP) | VAF 25/66 reads (38%) | catalogued as rs1559139740; called by muse, mutect2, varscan2
- FAM98B | c.*279G>C | 3'UTR (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1161+56C>G | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs1376101608; called by muse, varscan2
- HIPK1 | c.*993del | 3'UTR (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- KBTBD12 | c.*444C>T | 3'UTR (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- KLF2 | c.-72C>G | 5'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- LCK | c.*222G>T | 3'UTR (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- NEURL1B | c.*4587_*4604delinsATACAACTTTGGCTTGTT | 3'UTR (ONP) | VAF 8/49 reads (16%) | called by pindel, varscan2*
- PGBD5 | chr1:230321682 G>A | 3'Flank (SNP) | VAF 39/71 reads (55%) | called by muse, mutect2, varscan2
- QKI | c.1009+805G>T | Intron (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- RBM20 | c.*577G>A | 3'UTR (SNP) | VAF 33/79 reads (42%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.*1718A>T | 3'UTR (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- RTL6 | c.*2132C>T | 3'UTR (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- SEMG1 | c.*35C>T | 3'UTR (SNP) | VAF 107/314 reads (34%) | called by muse, mutect2, varscan2
- TEPSIN | c.527-431G>A | Intron (SNP) | VAF 26/61 reads (43%) | catalogued as rs966499190; called by muse, mutect2, varscan2
- USP25 | c.*13C>T | 3'UTR (SNP) | VAF 129/361 reads (36%) | called by muse, mutect2, varscan2
- USP38 | c.*604G>A | 3'UTR (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- ZBED3 | c.*2020C>T | 3'UTR (SNP) | VAF 33/112 reads (29%) | called by muse, mutect2, varscan2
